Surgical pathology report (de-identified scan), TCGA case TCGA-50-5942, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5942-01A (Primary Tumor).

PATIENT HISTORY:

PRE OP DIAGNOSIS: Right lung cancer

Collection Date: [REDACTED]

POST OP DIAGNOSIS: Same

PROCEDURE: Right anterior thoracotomy, bronchoscopy, [REDACTED]

FINAL DIAGNOSIS:**PART 1: LUNG, RIGHT UPPER LOBE ANTERIOR SEGMENT, SEGMENTECTOMY –**

- A. WELL DIFFERENTIATED ADENOCARCINOMA WITH PAPILLARY FEATURES AND LEPIDIC GROWTH, 2.8 CM.
- B. THE CARCINOMA DOES NOT INVOLVE THE VISCERAL PLEURA (PL0).
- C. NO DEFINITIVE ANGIOLYMPHATIC INVASION.
- D. ~~NEGATIVE SURGICAL RESECTION MARGINS~~
- E. MILD CENTRIOBULAR EMPHYSEMA.

**PART 2: LUNG, RIGHT SECONDARY CARINA, BIOPSY –
SUPERFICIAL FRAGMENTS OF RESPIRATORY EPITHELIUM.****PART 3: GASTROINTESTINAL JUNCTION, BIOPSY –**

- A. SQUAMOUS ESOPHAGEAL AND COLUMNAR GASTRIC-TYPE MUCOSA WITH CHRONIC INFLAMMATION.
- B. NEGATIVE FOR INTESTINAL METAPLASIA.

PART 4: STOMACH, FUNDUS, BIOPSY –

- A. UNREMARKABLE FUNDIC/BODY TYPE GASTRIC MUCOSA.
- B. HELICOBACTER PYLORI ORGANISMS ARE NOT IDENTIFIED.

PART 5: RIB, RIGHT THIRD, EXCISION –

BENIGN OSTEOCARTILAGINOUS TISSUE AND BONE MARROW WITH PRESERVED TRILINEAGE MATURATION.

PART 6: LYMPH NODE, RIGHT LEVEL 10, EXCISION –

ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 7: LYMPH NODE, RIGHT LEVEL 11, EXCISION –

ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 8: LYMPH NODE, RIGHT LEVEL 4, EXCISION –

ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 9: LYMPH NODE, LEVEL 7, EXCISION –

ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Upper Lobe
LUNG SEGMENT(S) INVOLVED:	Anterior
PROCEDURE:	Segmental
TUMOR SIZE:	Maximum dimension: 2.8 cm Minor dimension: 1.8 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive adenocarcinoma
HISTOLOGIC GRADE:	G1, Well differentiated
MICROSCOPIC SATELLITES:	Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL EXTENSION/INVASION OF TUMOR:	None identified
ANGIOLYMPHATIC INVASION:	No
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 2
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 2
UNDERLYING DISEASE(S):	Emphysema
T STAGE, PATHOLOGIC:	pT1
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
ANCILLARY STUDIES:	Histochemical stains

Source: NCI Genomic Data Commons file aacb4587-43a7-466f-933c-2b648104317e (TCGA-50-5942.915634E0-D38B-4A37-B96F-B9AC10507179.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).